Somatic mutation profile of tumor specimen TCGA-G3-AAV0-01A (aliquot TCGA-G3-AAV0-01A-11D-A36X-10) from TCGA case TCGA-G3-AAV0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.2 years (21,249 days).
Specimen TCGA-G3-AAV0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23490b92-fbaa-43ec-b931-ad86ef8daa9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-AAV0-10A (Blood Derived Normal), aliquot TCGA-G3-AAV0-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28abf573-355a-45a7-8126-fc5256eac2b7

The open-access MAF lists 201 somatic variants for this specimen: 152 protein-altering or splice-affecting, 42 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 42, Frame Shift Del 9, Nonsense Mutation 8, Frame Shift Ins 5, Splice Site 5, Splice Region 3, RNA 2, 5'UTR 2, In Frame Ins 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 50/125 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 73/169 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRIO | c.4283G>A p.R1428Q | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs879255626, COSV60078769; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.2450T>A p.L817H | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711438; called by muse, mutect2, varscan2
- ACADM | c.945G>C p.E315D | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100897824; called by muse, mutect2, varscan2
- ADAM30 | c.2276A>G p.Q759R | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV101024000; called by muse, mutect2, varscan2
- ADGRV1 | c.13514T>C p.I4505T | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV67977542; called by muse, mutect2, varscan2
- AHCTF1 | c.3608C>A p.S1203* (on ENST00000366508; = p.S1177* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 28/314 reads (9%) | catalogued as COSV100404535; called by muse, mutect2
- AKAP13 | c.3605C>G p.S1202* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100774812, COSV63456649; called by muse, mutect2, varscan2
- ALB | c.1682C>G p.P561R | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99892430; called by muse, mutect2, varscan2
- AMBRA1 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV100095533; called by muse, mutect2, varscan2
- AOAH | c.1426-4_1441del p.X476_splice | Splice Site (DEL) | VAF 18/80 reads (23%) | catalogued as rs768260369; called by pindel, varscan2
- AP2B1 | c.1438-2A>T p.X480_splice | Splice Site (SNP) | VAF 22/61 reads (36%) | catalogued as COSV99251784; called by muse, mutect2, varscan2
- ASH1L | c.1202A>T p.N401I | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV100853619; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2524T>G p.F842V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV100377203; called by muse, mutect2, varscan2
- BHMT2 | c.992A>C p.K331T | Missense Mutation (SNP) | VAF 103/295 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV99670319; called by muse, mutect2, varscan2
- BPIFB4 | c.298G>T p.G100W | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100971675; called by muse, mutect2, varscan2
- C2 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV54959120; called by muse, mutect2, varscan2
- CAPN6 | c.1657C>A p.P553T | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.223); catalogued as COSV100137129; called by muse, mutect2, varscan2
- CD163L1 | c.1449C>A p.S483R | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV100550767; called by muse, mutect2, varscan2
- CD33 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV99220850; called by muse, mutect2, varscan2
- CDC42EP5 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV100003010; called by muse, mutect2
- CDS1 | c.1274A>C p.K425T | Missense Mutation (SNP) | VAF 103/142 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as COSV99881179; called by muse, mutect2, varscan2
- CHD5 | c.1142A>C p.K381T | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as COSV99315347; called by muse, mutect2, varscan2
- CRACD | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as rs370638037, COSV51726252, COSV99073097; called by muse, mutect2, varscan2
- CREBBP | c.7031G>A p.R2344Q | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs753595183, COSV99272551; called by muse, mutect2, varscan2
- CRLF3 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100158571; called by muse, mutect2
- CSDE1 | c.2141_2142insC p.D715Rfs*2 (on ENST00000358528 / NM_001007553.3; = p.D684Rfs*2 on NM_007158.6) | Frame Shift Ins (INS) | VAF 33/109 reads (30%) | catalogued as COSV99796177; called by mutect2, pindel, varscan2
- CTNNA1 | c.2399T>A p.V800E | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100243314; called by muse, mutect2, varscan2
- CYP2C9 | c.1237C>A p.L413M | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99582778, COSV99583313; called by muse, mutect2, varscan2
- DAXX | c.1174A>C p.K392Q | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99802774; called by muse, mutect2, varscan2
- DNAH8 | c.2044G>A p.V682M | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1210165593, COSV100544278, COSV100547363; called by muse, mutect2, varscan2
- DNAH9 | c.6442T>C p.F2148L | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767566644, COSV99308562; called by muse, mutect2, varscan2
- DNAJC6 | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1375384108, COSV99675780; called by muse, varscan2
- EPHA8 | c.226A>C p.M76L | Missense Mutation (SNP) | VAF 99/250 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); catalogued as COSV99385847; called by muse, varscan2
- ERCC2 | c.215A>T p.Y72F | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV55538855, COSV99676553; called by muse, varscan2
- EXOC6 | c.603A>C p.K201N | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV99592607; called by muse, mutect2, varscan2
- FMNL2 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 141/304 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99981068; called by muse, mutect2, varscan2
- FN1 | c.5306A>T p.N1769I | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.99); catalogued as COSV100118476; called by muse, mutect2, varscan2
- FST | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1160465727, COSV99887538; called by muse, mutect2, varscan2
- GABRA2 | c.828A>T p.R276S | Missense Mutation (SNP) | VAF 136/298 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100734817; called by muse, mutect2, varscan2
- GAD2 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.515); catalogued as rs145658372; called by muse, varscan2
- GLIS1 | c.842T>G p.I281S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100391080; called by muse, mutect2, varscan2
- GOLGB1 | c.8630A>T p.Q2877L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV100511627; called by muse, mutect2, varscan2
- GPR146 | c.254T>G p.L85R | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99866569; called by muse, mutect2, varscan2
- GRIA3 | c.1534A>C p.T512P | Missense Mutation (SNP) | VAF 121/279 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99992090; called by muse, mutect2, varscan2
- HDAC5 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as COSV99871140; called by muse, mutect2, varscan2
- HGF | c.2054G>T p.R685I | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV99738770; called by muse, mutect2
- HMGCL | c.138T>G p.N46K | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV99354129; called by muse, varscan2
- HNRNPUL1 | c.999G>T p.A333= | Splice Region (SNP) | VAF 43/192 reads (22%) | catalogued as COSV54562029, COSV99647674; called by muse, mutect2, varscan2
- HRG | c.1001C>T p.T334I | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs774629799, COSV99215136; called by muse, mutect2, varscan2
- HRH1 | c.161G>T p.S54I | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as COSV101229119; called by muse, mutect2, varscan2
- IGDCC4 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV61535278; called by muse, mutect2
- IMMT | c.1130C>A p.T377N | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99607687; called by muse, mutect2, varscan2
- IRGC | c.1133T>G p.F378C | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99746612; called by muse, mutect2, varscan2
- IRS2 | c.3719G>A p.R1240H | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); catalogued as COSV65480590; called by muse, varscan2
- ITGA2 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 52/129 reads (40%) | catalogued as rs1300123988, COSV99671765; called by muse, mutect2, varscan2
- ITGA2B | c.2707C>A p.L903I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.471); catalogued as COSV99289326; called by muse, mutect2, varscan2
- JADE1 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs369651997; called by muse, mutect2, varscan2
- KCND2 | c.1363A>G p.N455D | Missense Mutation (SNP) | VAF 131/317 reads (41%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV100479070; called by muse, mutect2, varscan2
- KCNQ3 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 119/309 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV101196532; called by muse, mutect2, varscan2
- KLK6 | c.592G>T p.G198W | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485515531, COSV100037879; called by muse, mutect2, varscan2
- KMT2D | c.9284G>A p.G3095D | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.299); catalogued as COSV56440170; called by muse, mutect2, varscan2
- LCP2 | c.756A>C p.R252S | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99253637; called by muse, mutect2, varscan2
- LGR6 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.095); catalogued as rs1290758808, COSV100938285; called by muse, mutect2, varscan2
- LONP2 | c.2444T>C p.V815A | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.681); catalogued as COSV99589581; called by muse, mutect2, varscan2
- LOXL2 | c.367T>G p.L123V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV101207993; called by muse, mutect2, varscan2
- LRRC57 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV99535570; called by muse, mutect2, varscan2
- LRRK2 | c.1700T>C p.I567T | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs1185350430, COSV100111314; called by muse, mutect2, varscan2
- MAST2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100788873; called by muse, mutect2, varscan2
- MCF2L | c.3253G>A p.V1085M (on ENST00000375608; = p.V1053M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/177 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as rs1295418577, COSV99996233; called by muse, mutect2, varscan2
- MCM3 | c.1999-2A>T p.X667_splice (on ENST00000229854 / NM_001366374.2; = p.X657_splice on NM_002388.6 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 40/103 reads (39%) | catalogued as COSV100009142; called by muse, mutect2, varscan2
- METTL18 | c.700A>T p.N234Y | Missense Mutation (SNP) | VAF 80/269 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99610252; called by muse, mutect2, varscan2
- METTL24 | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs757373983, COSV100133690; called by muse, mutect2, varscan2
- MVB12A | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761237198, COSV100396640; called by muse, mutect2, varscan2
- MYO7A | c.2359T>C p.Y787H | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV101289299; called by muse, mutect2, varscan2
- NEDD9 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101053443; called by muse, mutect2, varscan2
- NKTR | c.1675C>A p.H559N | Missense Mutation (SNP) | VAF 136/304 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.069); catalogued as COSV99236482; called by muse, mutect2, varscan2
- NTAN1 | c.831dup p.H278Tfs*13 | Frame Shift Ins (INS) | VAF 54/136 reads (40%) | catalogued as rs780770021; called by mutect2, varscan2
- OR2G2 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100190042; called by muse, mutect2, varscan2
- OR2J3 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101013673; called by muse, mutect2, varscan2
- OR4D2 | c.32A>T p.D11V | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV101613870; called by muse, mutect2, varscan2
- OR4Q3 | c.869T>C p.M290T | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV100057452; called by muse, mutect2, varscan2
- OR5L1 | c.119T>A p.L40* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as COSV100450301; called by muse, mutect2, varscan2
- PAH | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as CM112733, COSV100188334, COSV100188480; called by muse, mutect2, varscan2
- PCF11 | c.1771T>C p.S591P | Missense Mutation (SNP) | VAF 132/428 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV53530992; called by muse, varscan2
- PCLO | c.11364T>A p.D3788E | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100438833; called by muse, mutect2, varscan2
- PDIA6 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99694977; called by muse, mutect2, varscan2
- PEAK3 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1348552337, COSV100457510; called by muse, mutect2
- PGLYRP4 | c.402T>A p.N134K | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV100668541; called by muse, mutect2, varscan2
- PIH1D2 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 62/87 reads (71%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99735651; called by muse, mutect2, varscan2
- PLAT | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs762297581, COSV99535338, COSV99535477; called by muse, mutect2, varscan2
- POTEE | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs1445448029, COSV100389174; called by muse, mutect2, varscan2
- PRIM1 | c.674A>T p.E225V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV100590507; called by muse, mutect2, varscan2
- PRRC2C | c.4411G>A p.V1471I (on ENST00000367742; = p.V1469I on NM_015172.4) | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100146210; called by muse, mutect2, varscan2
- RASAL2 | c.384+2T>C p.X128_splice | Splice Site (SNP) | VAF 38/146 reads (26%) | catalogued as COSV100862968; called by muse, mutect2, varscan2
- RBM7 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100348471; called by muse, mutect2, varscan2
- RECQL4 | c.3376G>A p.E1126K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.366); catalogued as rs779826649, COSV56743723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGL2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.964); catalogued as rs562018570, COSV69916466; called by muse, mutect2, varscan2
- RPS6KB2 | c.509C>A p.T170K | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV100412252, COSV100412404; called by muse, mutect2, varscan2
- RSAD2 | c.34A>T p.K12* | Nonsense Mutation (SNP) | VAF 38/125 reads (30%) | catalogued as COSV101150069; called by muse, mutect2, varscan2
- RYR1 | c.14309T>A p.M4770K | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as COSV100617198; called by muse, mutect2, varscan2
- SAFB | c.549A>G p.I183M | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV99413234; called by muse, mutect2, varscan2
- SECTM1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs766594826, COSV99486396; called by muse, mutect2, varscan2
- SHANK1 | c.4852G>T p.D1618Y | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99521976, COSV99522198; called by muse, mutect2, varscan2
- SKIV2L | c.2020C>G p.R674G | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100514867, COSV61714133; called by muse, mutect2, varscan2
- SLC17A7 | c.652del p.A218Rfs*68 | Frame Shift Del (DEL) | VAF 69/415 reads (17%) | catalogued as COSV99676689; called by mutect2, pindel, varscan2
- SLC35D1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV99338575; called by muse, mutect2, varscan2
- SLC46A2 | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100953524; called by muse, mutect2, varscan2
- SND1 | c.2576G>A p.G859E | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61250447; called by muse, mutect2, varscan2
- SPATA17 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 93/165 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as rs751177918, COSV100861239; called by muse, mutect2, varscan2
- SYNE1 | c.11768A>G p.D3923G | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV55131554, COSV99582160; called by muse, mutect2
- SYT14 | c.1520A>G p.N507S | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV99656279; called by muse, mutect2, varscan2
- TBC1D32 | c.980T>G p.V327G | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV99251498; called by muse, mutect2
- TBC1D9 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV101464415; called by muse, mutect2, varscan2
- TBCCD1 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 7/204 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV100112174; called by muse, mutect2
- TBL1XR1 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 109/274 reads (40%) | catalogued as COSV101467823; called by muse, mutect2, varscan2
- TGFBI | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100526732; called by muse, mutect2, varscan2
- TM9SF2 | c.1489-2A>T p.X497_splice | Splice Site (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100899786; called by muse, mutect2, varscan2
- TRAFD1 | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); catalogued as COSV99987022; called by muse, mutect2
- TRIML1 | c.892T>A p.Y298N | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV100206373; called by muse, mutect2, varscan2
- TRPA1 | c.2014A>C p.K672Q | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV100085400; called by muse, mutect2, varscan2
- TTC39C | c.368C>T p.P123L (on ENST00000317571 / NM_001135993.2; = p.P62L on NM_153211.4) | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs750316061, COSV58215633; called by muse, mutect2, varscan2
- TTN | c.7187A>T p.Q2396L (on ENST00000591111; = p.Q2350L on NM_003319.4) | Missense Mutation (SNP) | VAF 43/106 reads (41%) | PolyPhen benign (0.109); catalogued as COSV100633517; called by muse, mutect2, varscan2
- UBE4B | c.2185G>C p.A729P (on ENST00000343090 / NM_001105562.3; = p.A600P on NM_006048.5) | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); catalogued as COSV99477826; called by muse, mutect2, varscan2
- UBXN2A | c.228C>G p.D76E | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as COSV100465345; called by muse, mutect2, varscan2
- UROC1 | c.25T>G p.S9A | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV52036807, COSV99332513; called by muse, mutect2, varscan2
- VDAC1 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | catalogued as COSV99527353; called by muse, mutect2, varscan2
- VPS54 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV55438195, COSV55444894, COSV99708893; called by muse, mutect2, varscan2
- XIRP2 | c.1888G>T p.V630L (on ENST00000628543; = p.V805L on NM_152381.6) | Missense Mutation (SNP) | VAF 168/375 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99748286; called by muse, mutect2, varscan2
- ZFYVE9 | c.1955A>T p.Y652F | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99820820; called by muse, mutect2, varscan2
- ZGRF1 | c.2538A>T p.K846N | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as COSV100005853; called by muse, mutect2, varscan2
- ZNF14 | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100694165; called by muse, mutect2, varscan2
- ZNF20 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100503193; called by muse, mutect2, varscan2
- AHDC1 | c.4266_4308del p.C1422Wfs*9 | Frame Shift Del (DEL) | VAF 33/81 reads (41%) | called by mutect2, pindel
- CELSR2 | c.374dup p.Q126Tfs*87 | Frame Shift Ins (INS) | VAF 48/141 reads (34%) | called by mutect2, pindel, varscan2
- DIP2A | c.4160del p.G1387Efs*5 | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | called by mutect2, pindel, varscan2
- DKKL1 | c.299_307dup p.L100_S102dup | In Frame Ins (INS) | VAF 23/124 reads (19%) | called by mutect2, varscan2
- EPHA8 | c.256_257del p.T86Efs*14 | Frame Shift Del (DEL) | VAF 76/222 reads (34%) | called by pindel, varscan2
- FRG2C | c.340T>C p.C114R | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD11B1 | c.174_187dup p.V63Efs*6 | Frame Shift Ins (INS) | VAF 34/122 reads (28%) | called by mutect2, varscan2
- KRT75 | c.674del p.L225Rfs*30 | Frame Shift Del (DEL) | VAF 44/123 reads (36%) | called by mutect2, pindel, varscan2
- MRPL35 | c.368del p.V123Gfs*22 | Frame Shift Del (DEL) | VAF 53/160 reads (33%) | called by mutect2, pindel, varscan2
- OR2T3 | c.880A>T p.I294F | Missense Mutation (SNP) | VAF 142/1131 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2
- PCF11 | c.1812_1814dup p.N604dup | In Frame Ins (INS) | VAF 76/382 reads (20%) | called by pindel, varscan2
- PCK1 | c.1396_1414delinsT p.A466_G472delinsC | Splice Region (DEL) | VAF 51/174 reads (29%) | called by pindel, varscan2*
- REV3L | c.3704del p.S1235Lfs*9 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- RFC1 | c.242dup p.N81Kfs*14 | Frame Shift Ins (INS) | VAF 12/111 reads (11%) | called by mutect2, pindel, varscan2
- SULT4A1 | c.225_226del p.D75Efs*45 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- TMED1 | c.564_577del p.N189Qfs*81 | Frame Shift Del (DEL) | VAF 32/120 reads (27%) | called by mutect2, pindel, varscan2
- TTR | c.336+4_336+5del | Splice Region (DEL) | VAF 56/170 reads (33%) | called by mutect2, pindel, varscan2
- WAPL | c.1985_1996del p.L662_K666delins* | Nonsense Mutation (DEL) | VAF 135/379 reads (36%) | called by mutect2, pindel, varscan2
- ADRA2A | c.1161C>T p.F387= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99701851; called by muse, mutect2, varscan2
- AGBL1 | c.2055C>T p.G685= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV101224364; called by muse, mutect2
- AQP3 | c.573G>A p.E191= | Silent (SNP) | VAF 66/184 reads (36%) | catalogued as COSV99955726; called by muse, mutect2, varscan2
- BSN | c.7968C>A p.A2656= | Silent (SNP) | VAF 57/147 reads (39%) | catalogued as COSV56523426, COSV99610032; called by muse, mutect2, varscan2
- CAMSAP2 | c.3390T>C p.D1130= (on ENST00000236925 / NM_001297707.2; = p.D1119= on NM_203459.3) | Silent (SNP) | VAF 157/289 reads (54%) | catalogued as COSV99374471; called by muse, mutect2, varscan2
- CHD6 | c.864A>G p.E288= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV100498753; called by muse, mutect2, varscan2
- COX15 | c.1053A>G p.R351= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV99187869; called by muse, mutect2, varscan2
- FBN3 | c.2424C>T p.T808= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV99561988; called by muse, mutect2, varscan2
- FCGBP | c.10176G>A p.G3392= | Silent (SNP) | VAF 57/251 reads (23%) | called by muse, mutect2, varscan2
- FN3KRP | c.750C>T p.G250= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV99485136; called by muse, mutect2, varscan2
- GJB5 | c.510C>G p.P170= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100258650, COSV100258743; called by muse, mutect2, varscan2
- HDAC5 | c.219G>A p.E73= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as rs751619090, COSV99871143; called by muse, mutect2, varscan2
- HIVEP3 | c.7098A>T p.P2366= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99914207; called by muse, mutect2, varscan2
- HNRNPH1 | c.459G>A p.G153= | Silent (SNP) | VAF 75/184 reads (41%) | catalogued as COSV100271019; called by muse, mutect2, varscan2
- INO80D | c.1188G>A p.K396= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV101124802; called by muse, varscan2
- INTS4 | c.756A>T p.A252= | Silent (SNP) | VAF 379/663 reads (57%) | catalogued as COSV101417297; called by muse, mutect2, varscan2
- KDM3B | c.243A>G p.K81= | Silent (SNP) | VAF 57/127 reads (45%) | catalogued as COSV100070323; called by muse, mutect2, varscan2
- KIAA1549L | c.1296T>A p.I432= (on ENST00000321505; = p.I729= on NM_012194.3) | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV99684636; called by muse, mutect2, varscan2
- LAMA3 | c.1146C>T p.G382= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV100557751; called by muse, mutect2, varscan2
- LAMB2 | c.1822C>T p.L608= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as COSV100565545; called by muse, mutect2, varscan2
- LPAR2 | c.723G>A p.K241= | Silent (SNP) | VAF 56/213 reads (26%) | catalogued as COSV99179656; called by muse, mutect2, varscan2
- LTBP1 | c.2637G>A p.V879= (on ENST00000404816 / NM_206943.4; = p.V553= on NM_000627.4) | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV100618024; called by muse, mutect2, varscan2
- MGA | c.1560C>T p.F520= | Silent (SNP) | VAF 60/159 reads (38%) | catalogued as rs764790937, COSV99581879; called by muse, mutect2, varscan2
- MRAP | c.6C>T p.A2= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV100353365; called by muse, mutect2, varscan2
- MUC21 | c.1374T>G p.T458= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as COSV66220083; called by muse, mutect2, varscan2
- NCOA1 | c.1320T>C p.S440= | Silent (SNP) | VAF 46/174 reads (26%) | catalogued as COSV99947247; called by muse, mutect2, varscan2
- NOM1 | c.603G>A p.K201= | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as COSV99316164; called by muse, mutect2, varscan2
- PODXL2 | c.1713G>T p.L571= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99230193; called by muse, mutect2, varscan2
- PPP2R3A | c.939T>C p.N313= | Silent (SNP) | VAF 58/149 reads (39%) | catalogued as COSV99388334; called by muse, mutect2, varscan2
- PPP6R1 | c.579G>A p.Q193= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs1352805877, COSV101337019; called by muse, mutect2, varscan2
- PRTG | c.855A>C p.G285= | Silent (SNP) | VAF 85/205 reads (41%) | catalogued as COSV101221510; called by muse, mutect2, varscan2
- PTPN7 | c.984A>C p.L328= (on ENST00000495688; = p.L367= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV100460190; called by muse, mutect2, varscan2
- RASAL1 | c.48G>A p.A16= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV99922184; called by muse, mutect2, varscan2
- RIMS1 | c.3936A>G p.Q1312= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV99331035; called by muse, mutect2, varscan2
- SFRP4 | c.246G>A p.A82= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs750458196, COSV99554727; called by muse, mutect2, varscan2
- SNX17 | c.834G>A p.V278= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV99278090; called by muse, mutect2, varscan2
- SPATA5 | c.1587G>A p.R529= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV99916304; called by muse, mutect2, varscan2
- ST13 | c.75C>G p.T25= | Silent (SNP) | VAF 27/475 reads (6%) | called by muse, mutect2
- TAF4B | c.2382T>A p.I794= | Silent (SNP) | VAF 206/520 reads (40%) | catalogued as COSV99301107; called by muse, mutect2, varscan2
- TPRG1L | c.225G>A p.V75= | Silent (SNP) | VAF 63/156 reads (40%) | catalogued as COSV100754792; called by muse, mutect2, varscan2
- TRMT10C | c.1059A>G p.L353= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as rs775696131, COSV99998418; called by muse, mutect2, varscan2
- XIRP2 | c.1887G>T p.G629= (on ENST00000628543; = p.G804= on NM_152381.6) | Silent (SNP) | VAF 168/377 reads (45%) | catalogued as COSV54728822, COSV99748283; called by muse, mutect2, varscan2
- ABL2 | c.158-9652C>A | Intron (SNP) | VAF 42/159 reads (26%) | catalogued as COSV100773099; called by muse, mutect2, varscan2
- CRIP3 | chr6:43308794 del GCTCC | 5'UTR (DEL) | VAF 31/127 reads (24%) | called by pindel, varscan2
- DCHS2 | n.5610A>T | RNA (SNP) | VAF 29/56 reads (52%) | catalogued as COSV100602784; called by muse, mutect2, varscan2
- DNAJA4 | chr15:78264366 ins AAAGG | 5'Flank (INS) | VAF 10/19 reads (53%) | called by mutect2, varscan2
- RN7SL484P | chr15:99792218 A>G | 3'Flank (SNP) | VAF 6/12 reads (50%) | called by muse, varscan2
- TIMM50 | c.-15del | 5'UTR (DEL) | VAF 17/74 reads (23%) | called by mutect2, pindel, varscan2
- ZNF271P | n.1289T>G | RNA (SNP) | VAF 65/143 reads (45%) | catalogued as rs1297240359; called by muse, mutect2, varscan2
